Surgical pathology report (de-identified scan), TCGA case TCGA-43-A475, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-A475-01A (Primary Tumor).

[page 1 of 2]
1CD03

carcinoma, squamous
cell, NOS 807013

Site: lung, upper lobe
C34.1

Final Surgical Pathology Report

Procedure:

Diagnosis

A. Lung, right upper lobe, resection: Poorly differentiated squamous cell carcinoma

B. Lymph node, level X, biopsy: There is no evidence of malignancy in a single lymph node

C. Rib, second, biopsy: Carcinoma is present in pericostal soft tissue

D. Lymph node, R4, biopsy: There is no evidence of malignancy in any of 9 pieces of lymph node

E. Lymph node, level VII, biopsy: There is no evidence of malignancy in any of 5 pieces of lymph nodes

Microscopic Description:

A.

Histologic type: Poorly differentiated squamous cell carcinoma. A mucicarmine stain is negative.

Histologic grade: 3 of 3

Mitotic index: 12 mitoses/10 HPFs (1 HPF = 0.196 sq mm)

Tumor size: 1.8 cm in the lung, 2 cm with the overlying tumor

Bronchial resection margin: Negative for malignancy

Pulmonary margin of resection: Negative for malignancy

Pleura: Carcinoma penetrates through the pleura into skeletal muscle and is present on the adherent soft tissue surface on the specimen.

Vascular invasion: Absent

Attached lymph nodes: There is no evidence of malignancy in either of two hilar lymph nodes

pTNM stage: T3 N0

Non-tumorous lung: Emphysema

Antibody...Results...Comment

TTF1 ... Negative

p63 ... Positive

CK5/6 ... Positive

Paraffin sections; 10% neutral buffered formalin; Controls stain appropriately.

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents.

These antibodies are monitored and controlled in our laboratory and their performance for

in vitro diagnosis is well described in the medical literature.

They have not been cleared

or approved by the FDA.]

C. Sections of rib show normal bone, cartilage and bone marrow, but there is carcinoma in pericostal soft tissue.

Specimen

A. Right upper lobe

B. Level X

C. Portion of second rib

D. R4

E. Level VII lymph node

9-5-12
RD

[page 2 of 2]
Clinical Information
Lung nodule

Gross Description

The specimen is received unfixed labeled right upper lobe and consists of a 179 g lung lobe measuring 16.5 x 10.5 x 3 cm. The serosal surface is pink to purple. There is a palpable mass that appears to be apical in the specimen and measures 1.8 by 1.2 cm in cross section. There is some adherent soft tissue on the serosal surface over the tumor that measures 3.6 by 2.6 cm by 0.6 cm. A portion of the specimen is taken for research purposes. Sections after fixation

Block summary: 1 - bronchial margin and lymph node; 2 - vascular margin and lymph node; 3,4 pulmonary margins; 5-7 tumor; 8-10 benign lung.

Specimen B. is received unfixed labeled level X and consists of 2 pieces of black soft tissue measuring 1 cm in greatest aggregate dimension. AS-1

Specimen C. is received unfixed of a portion of second rib and consists of multiple pieces of pink and red bone measuring 5 by 1.5 x 0.7 cm in aggregate. Sections after fixation and decalcification.

Specimen D. is received unfixed labeled R4 and consists of multiple pieces of red and black soft tissue occupying approximately 2 mL in volume. AS-2

Specimen E. is received unfixed labeled level VII lymph node and consists of 2 pieces of pink yellow and black soft tissue measuring 2 cm in greatest aggregate dimension. AS-1

Signosis Discrepancy		
Tumor Malignancy History		

8/23/12

Source: NCI Genomic Data Commons file db812925-9826-497e-85d4-2a10d1771c92 (TCGA-43-A475.24B44F94-4883-492D-A373-626D240014A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).